Somatic mutation profile of tumor specimen TCGA-V1-A9ZI-01A (aliquot TCGA-V1-A9ZI-01A-11D-A41K-08) from TCGA case TCGA-V1-A9ZI, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9ZI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b5233b0-49c1-4b30-91eb-38540e52fcfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9ZI-10A (Blood Derived Normal), aliquot TCGA-V1-A9ZI-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93b8c75d-253b-4369-bac4-f0b808b25a44

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Frame Shift Del 4, Intron 2, In Frame Del 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.626_627del p.R209Kfs*6 | Frame Shift Del (DEL) | VAF 15/27 reads (56%) | catalogued as rs1057517840; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABHD14A-ACY1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 92/246 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV99587531; called by muse, mutect2, varscan2
- ADGRG3 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs554076542, COSV59651172; called by muse, mutect2, varscan2
- AGER | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV100426094; called by muse, mutect2, varscan2
- AHNAK | c.4975G>A p.D1659N | Missense Mutation (SNP) | VAF 150/337 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs757961380, COSV99945534; called by muse, mutect2, varscan2
- ARHGAP5 | c.3829T>G p.F1277V (on ENST00000345122 / NM_001030055.2; = p.F1276V on NM_001173.3) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100564999; called by muse, mutect2, varscan2
- CD200R1 | c.640G>A p.V214M (on ENST00000471858 / NM_170780.3; = p.V237M on NM_138806.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as rs867172045, COSV55599180; called by muse, mutect2, varscan2
- CSF1R | c.1738A>C p.N580H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99640776; called by muse, mutect2, varscan2
- CSMD1 | c.8152G>A p.V2718M (on ENST00000520002; = p.V2717M on NM_033225.6) | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs779488083, COSV59370438; called by muse, mutect2, varscan2
- GLYATL2 | c.641G>C p.W214S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99780181; called by muse, mutect2, varscan2
- GRM4 | c.2329G>A p.V777M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs746693453, COSV100945720; called by muse, mutect2, varscan2
- IL6ST | c.476C>G p.T159S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV100410614, COSV61142916; called by muse, mutect2, varscan2
- IQCF2 | c.338G>A p.W113* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as COSV100290995; called by muse, mutect2, varscan2
- MRGPRX2 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs779414608, COSV61673849; called by muse, mutect2, varscan2
- PCDHGA2 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.358); catalogued as rs1355486436, COSV53928692; called by muse, mutect2
- SLC6A15 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as rs368561170, COSV57022159; called by muse, mutect2, varscan2
- SNRPA1 | c.715A>C p.T239P | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as COSV99574427; called by muse, mutect2, varscan2
- ST18 | c.2551C>A p.P851T | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.218); catalogued as COSV52506502, COSV99388165; called by muse, mutect2
- TUBA4A | c.602C>G p.A201G | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as COSV99944599; called by muse, mutect2, varscan2
- C2CD3 | c.2659dup p.V887Gfs*28 | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- CD6 | c.26_33del p.G9Dfs*14 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- CDC25B | c.698_700del p.D233_L234delinsV (on ENST00000245960 / NM_021873.3; = p.D219_L220delinsV on NM_004358.4) | In Frame Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- CELSR3 | c.2542_2552del p.I848Qfs*18 | Frame Shift Del (DEL) | VAF 33/103 reads (32%) | called by mutect2, pindel, varscan2
- KMT2D | c.10317_10326del p.M3439Ifs*9 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- SNTG1 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.083); called by muse, mutect2
- TMPRSS2 | c.955_999del p.F319_S333del | In Frame Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel
- ABCA3 | c.3795C>T p.Y1265= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as rs140948738; called by muse, mutect2, varscan2
- ALPG | c.18G>T p.V6= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV99779148; called by muse, mutect2, varscan2
- LRRC4C | c.1194G>A p.A398= | Silent (SNP) | VAF 74/191 reads (39%) | catalogued as rs370082164; called by muse, mutect2, varscan2
- NCBP1 | c.2118A>G p.Q706= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV100910599; called by muse, mutect2, varscan2
- PPP1R12C | c.2040C>T p.D680= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs748508891, COSV99135647; called by muse, varscan2
- RP1 | c.2535G>A p.G845= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as COSV99606259; called by muse, mutect2, varscan2
- XKR3 | c.429G>A p.T143= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV58885384; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+16del | Intron (DEL) | VAF 4/36 reads (11%) | catalogued as rs766264675; called by pindel, varscan2
- ALKBH3 | c.460-4234C>G | Intron (SNP) | VAF 29/90 reads (32%) | catalogued as COSV100236063; called by muse, mutect2, varscan2
